Gene-level copy-number profile of tumor specimen TCGA-4P-AA8J-01A from TCGA case TCGA-4P-AA8J, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 66.3 years (24,222 days).
Specimen TCGA-4P-AA8J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.626182cd-98a8-4fd1-952d-ee1fdd2ba7a3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-4P-AA8J-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e9b67576-8a1b-4a34-ba5a-ac88746de727

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 11,717; copy number 2: 43,607; copy number 3: 3,642; copy number 4: 718; copy number 5: 28; copy number 25: 66; copy number 27: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-4P-AA8J-01A-11D-A390-01): tumor purity 0.36, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:51,489,100–51,730,727, 1 gene (within-gene range 0–1): FRMD6.
- chr14:51,637,348–52,156,179, 19 genes: AL122125.1, FRMD6-AS1, RNA5SP385, RNU6-301P, AL079307.2, OR7E105P, OR7E106P, AL079307.1, OR7E159P, AL079307.3, GNG2, AL358333.2, AL358333.3, AL358333.1, RTRAF, NID2, LINC02319, COX5AP2, AL118557.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 107 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:17,980,868–18,177,397, 13 genes, copy number 27: MIR648, AC016027.3, AC016027.2, RHEBP3, LINC01634, AC016027.1, PEX26, AC016027.5, AC016027.4, ARL2BPP10, TUBA8, AC008079.1, USP18.
- chr22:19,756,703–21,345,258, 94 genes, copy number 5–25 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,296. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
